Somatic mutation profile of tumor specimen ALCH-B1T7-TTP1-A (aliquot ALCH-B1T7-TTP1-A-2-0-D-A76B-36) from ALCHEMIST case ALCH-B1T7, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 60.4 years (22,052 days).
Specimen ALCH-B1T7-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e2095435-228b-4e5a-9ebe-ef268d67c812.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1T7-NB1-A (Blood Derived Normal), aliquot ALCH-B1T7-NB1-A-1-0-D-A76B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b11f9b0a-d0b3-42b1-897d-88aa6ee2abb3

The open-access MAF lists 28 somatic variants for this specimen: 19 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 8, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 18/304 reads (6%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2
- F9 | c.827C>T p.T276I | Missense Mutation (SNP) | VAF 14/145 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0.302); catalogued as CD035542; called by muse, mutect2
- FLG | c.7640C>T p.S2547L | Missense Mutation (SNP) | VAF 48/475 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.022); catalogued as rs369029216, COSV64242857; called by muse, mutect2, varscan2
- H2BC18 | c.214G>C p.E72Q | Missense Mutation (SNP) | VAF 35/533 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.279); catalogued as COSV100516073; called by muse, mutect2
- H2BC21 | c.214G>C p.E72Q | Missense Mutation (SNP) | VAF 26/737 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.052); catalogued as COSV100480192; called by muse, mutect2
- IRAG2 | c.2908G>T p.V970L (on ENST00000636465; = p.V15L on NM_006152.4 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/408 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs143325687, COSV63140072; called by muse, mutect2
- NLRP3 | c.1749C>A p.N583K | Missense Mutation (SNP) | VAF 36/970 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.258); catalogued as COSV60221957; called by muse, mutect2
- OR6K2 | c.785G>T p.R262L | Missense Mutation (SNP) | VAF 22/332 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV62743276, COSV62743573; called by muse, mutect2
- TRGV1 | c.137C>A p.A46E | Missense Mutation (SNP) | VAF 17/493 reads (3%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1386397896; called by muse, mutect2
- FAM178B | c.1831C>T p.Q611* (on ENST00000490605 / NM_001122646.3; = p.Q51* on NM_016490.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 14/338 reads (4%) | called by muse, mutect2
- FLG | c.6724A>G p.S2242G | Missense Mutation (SNP) | VAF 19/556 reads (3%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.892); called by muse, mutect2
- HRH4 | c.712C>G p.L238V | Missense Mutation (SNP) | VAF 7/134 reads (5%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.676); called by muse, mutect2
- MAGEB4 | c.349G>T p.V117L | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.101); called by muse, mutect2
- MRC2 | c.3110G>T p.G1037V | Missense Mutation (SNP) | VAF 16/346 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- NALCN | c.3982G>T p.V1328L | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2
- PCDH15 | c.1466A>G p.E489G | Missense Mutation (SNP) | VAF 11/210 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.656); called by muse, mutect2
- SPTA1 | c.6581C>A p.S2194Y | Missense Mutation (SNP) | VAF 13/177 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- TGIF2LX | c.518C>A p.P173Q | Missense Mutation (SNP) | VAF 36/476 reads (8%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.855); called by muse, mutect2
- USH2A | c.13314G>T p.W4438C | Missense Mutation (SNP) | VAF 10/209 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.43); called by muse, mutect2
- CFAP57 | c.1581G>T p.L527= | Silent (SNP) | VAF 7/172 reads (4%) | called by muse, mutect2
- FLG | c.6723C>A p.S2241= | Silent (SNP) | VAF 18/558 reads (3%) | catalogued as COSV100912136; called by muse, mutect2
- LGR6 | c.1815A>G p.A605= (on ENST00000367278 / NM_001017403.1; = p.A553= on NM_021636.3) | Silent (SNP) | VAF 28/436 reads (6%) | called by muse, mutect2
- LILRB1 | c.963C>A p.G321= (on ENST00000427581; = p.G285= on NM_006669.6) | Silent (SNP) | VAF 23/648 reads (4%) | called by muse, mutect2
- MAGEB4 | c.351G>T p.V117= | Silent (SNP) | VAF 8/127 reads (6%) | called by muse, mutect2
- MYADML2 | c.582C>A p.T194= | Silent (SNP) | VAF 12/214 reads (6%) | called by muse, mutect2
- NEB | c.2205T>C p.C735= | Silent (SNP) | VAF 9/189 reads (5%) | called by muse, mutect2
- ZNF469 | c.8139G>T p.G2713= (on ENST00000437464; = p.G2741= on NM_001367624.2) | Silent (SNP) | VAF 12/402 reads (3%) | called by muse, mutect2
- SDCBP2 | c.225+22G>T | Intron (SNP) | VAF 26/356 reads (7%) | called by muse, mutect2
